Somatic mutation profile of tumor specimen TARGET-20-PASSWG-03A (aliquot TARGET-20-PASSWG-03A-01D) from TARGET case TARGET-20-PASSWG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.3 years (113 days).
Specimen TARGET-20-PASSWG-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e72934e-fdad-4139-aa15-ec58d4dea73c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASSWG-10A (Blood Derived Normal), aliquot TARGET-20-PASSWG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/184b8fee-0fcb-4d56-9e22-bc65d8b6d8f0

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs730880472, COSV55534139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
